TCGA case TCGA-XF-A9T2 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa6b44ab-14b1-4b5d-8679-ba958b546afa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Dead; Days to death: 575 days (1.6 years).

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 54.6 years (19,945 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 5th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 141; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 54.5 years (19,910 days); Days to diagnosis: -35 days; AJCC pathologic T: T1.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -35 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Timepoint category: Prior to Procurement.
4. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary.
5. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Bilateral; Classification of tumor: Synchronous primary; Age at diagnosis: 55.0 years (20,079 days); Days to diagnosis: 134 days; AJCC staging edition: 5th; AJCC pathologic stage: Stage II.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 134 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Karnofsky performance status: 90.
- Follow-up contact recording only the day: day 575.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 121 kg; Height: 191 cm; BMI: 33.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: Medical Doctors.

Family history
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-A9T2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 460 mg.
  Slide TCGA-XF-A9T2-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-A9T2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-A9T2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Occupation current: Retired; Occupation primary: Dentist; Occupation primary industry: Dental Services; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; New tumor event diagnosis indicator: No.
- Stage record, Gleason grading: Gleason score: 6.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Transurethral resection alone.
- Other malignancy form 1: Malignancy type: Prior Malignancy.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Turbt.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 575 days; disease-specific survival: event status not recorded, 575 days; progression-free interval: no event (censored), 575 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-A9T2-01A-11D-A42D-01): tumor purity 0.84, ploidy 2, whole-genome doublings 0.
